Somatic mutation profile of tumor specimen TCGA-E7-A7DV-01A (aliquot TCGA-E7-A7DV-01A-11D-A339-08) from TCGA case TCGA-E7-A7DV, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 44.2 years (16,145 days).
Specimen TCGA-E7-A7DV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb2e04d0-664f-48dd-8a39-158a4ec413f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A7DV-10A (Blood Derived Normal), aliquot TCGA-E7-A7DV-10A-01D-A339-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c340b0e-648e-46fc-9c02-2416b9048990

The open-access MAF lists 324 somatic variants for this specimen: 241 protein-altering or splice-affecting, 79 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 215, Silent 79, Nonsense Mutation 19, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1, Splice Region 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913483, CM950470, COSV53390026; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.265-1G>A p.X89_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as rs796052953, CS072281, CS096237, COSV57670712, COSV57677485; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3292C>G p.Q1098E (on ENST00000404938 / NM_001163941.2; = p.Q653E on NM_178559.6) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV51714293, COSV99328899; called by muse, mutect2, varscan2
- ABHD16A | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs768974381, COSV65452105; called by muse, mutect2, varscan2
- ABHD16A | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.135); catalogued as COSV65443003; called by muse, varscan2
- ACACA | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs753354765; called by muse, mutect2
- ACAP3 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs1437353187, COSV57640209, COSV57642759; called by mutect2, varscan2
- ACP5 | c.903G>C p.E301D | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV54536762; called by muse, mutect2, varscan2
- ACSL3 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.964); catalogued as COSV62483421; called by muse, mutect2, varscan2
- ACSM4 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as rs936896432, COSV68068440; called by muse, mutect2, varscan2
- ACTN2 | c.63C>G p.I21M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV63976606; called by muse, mutect2, varscan2
- ADAM19 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV57434033; called by muse, mutect2, varscan2
- ADCY10 | c.3163C>G p.L1055V | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV63242499; called by muse, mutect2, varscan2
- ADCY9 | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as COSV53578082; called by muse, mutect2, varscan2
- AGAP1 | c.1167G>C p.Q389H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.958); catalogued as COSV58332328; called by mutect2, varscan2
- AGRN | c.2407G>A p.G803S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as rs538909713, COSV65070486; called by muse, mutect2, varscan2
- AKAP9 | c.5857G>A p.E1953K (on ENST00000359028; = p.E1921K on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62340918, COSV62351488; called by muse, mutect2, varscan2
- ALDH3A1 | c.1140G>C p.E380D | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as COSV56735984; called by muse, mutect2, varscan2
- ALDH3A1 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV56735996; called by muse, mutect2, varscan2
- AMIGO3 | c.512C>A p.S171* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as COSV100246523, COSV99047390; called by muse, mutect2, varscan2
- ANO2 | c.692C>G p.S231W (on ENST00000356134 / NM_001278597.3; = p.S235W on NM_001278596.3) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs772006493, COSV59012074, COSV59032011; called by muse, mutect2, varscan2
- ANOS1 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.713); catalogued as COSV99390746; called by muse, mutect2, varscan2
- APLF | c.691C>G p.Q231E | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV58146626; called by muse, mutect2, varscan2
- ARHGEF28 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV55262224; called by muse, mutect2, varscan2
- ATG16L1 | c.1525G>A p.D509N (on ENST00000392017 / NM_030803.7; = p.D490N on NM_017974.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100731298; called by mutect2, varscan2
- ATP11B | c.2263G>T p.D755Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as COSV60030560; called by muse, mutect2, varscan2
- ATP12A | c.2218C>G p.L740V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54519308; called by muse, mutect2, varscan2
- AXIN2 | c.957-1G>C p.X319_splice | Splice Site (SNP) | VAF 8/58 reads (14%) | catalogued as COSV61058810; called by muse, mutect2, varscan2
- BRIP1 | c.3334G>C p.D1112H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.579); catalogued as COSV52002912; called by muse, mutect2, varscan2
- BRMS1 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.039); catalogued as rs1159239724, COSV100240205; called by muse, mutect2
- C2CD3 | c.3076G>A p.E1026K | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58095483; called by muse, mutect2, varscan2
- C2CD3 | c.2891G>C p.R964T | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58090948; called by muse, mutect2, varscan2
- CACNA1B | c.3770G>A p.R1257Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1194337634, COSV53134475; called by muse, mutect2
- CAMK2D | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as COSV99593729; called by mutect2, varscan2
- CAMTA1 | c.317C>A p.S106* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100348270; called by muse, mutect2, varscan2
- CBX7 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs1338153360, COSV99334016; called by muse, mutect2
- CCDC40 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV53901499; called by muse, mutect2, varscan2
- CD1D | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1457194054, COSV63809430; called by muse, mutect2, varscan2
- CD5L | c.755T>A p.L252H | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV63822499; called by muse, mutect2
- CDC25A | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs374368943, COSV56769636; called by muse, mutect2, varscan2
- CEP120 | c.1894C>G p.L632V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100070983; called by muse, mutect2
- CEP126 | c.1196C>A p.S399Y | Missense Mutation (SNP) | VAF 112/196 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.209); catalogued as COSV54827703; called by muse, mutect2, varscan2
- CEP131 | c.952C>T p.Q318* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as COSV99488069; called by muse, mutect2, varscan2
- CFAP65 | c.3600C>G p.D1200E | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.06); catalogued as COSV58563401; called by muse, mutect2, varscan2
- CFHR2 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66381604; called by muse, mutect2, varscan2
- CHMP3 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as rs368950086; called by muse, mutect2, varscan2
- CIR1 | c.33G>C p.K11N | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55807090, COSV55808655; called by muse, mutect2, varscan2
- CKM | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53465982; called by muse, mutect2, varscan2
- CNTNAP4 | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs1317028512, COSV56663874; called by muse, mutect2, varscan2
- COG8 | c.17C>G p.T6S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV54742836; called by muse, mutect2
- COL12A1 | c.8416-1G>T p.X2806_splice | Splice Site (SNP) | VAF 24/133 reads (18%) | catalogued as COSV59400632; called by muse, mutect2, varscan2
- CRLF2 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV101053667; called by muse, mutect2, varscan2
- CRTAM | c.238C>G p.Q80E | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57069452; called by muse, mutect2, varscan2
- CXCL8 | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV56641181; called by muse, mutect2, varscan2
- CYP2E1 | c.1281C>G p.F427L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53314270; called by muse, mutect2, varscan2
- DDX46 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV62799857; called by muse, varscan2
- DDX46 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as COSV62799213; called by mutect2, varscan2
- DENND10 | c.591C>G p.T197= | Splice Region (SNP) | VAF 8/36 reads (22%) | catalogued as COSV63857894; called by muse, mutect2, varscan2
- DGKD | c.1973G>C p.R658T (on ENST00000264057 / NM_152879.3; = p.R614T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV51065849; called by muse, mutect2, varscan2
- DGKE | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV99400854; called by muse, mutect2
- DHX9 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62360664; called by muse, mutect2, varscan2
- DICER1 | c.1999C>G p.L667V | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.763); catalogued as COSV58623669; called by muse, mutect2
- DMAC2L | c.468C>G p.I156M | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV55413179, COSV55413844; called by muse, mutect2, varscan2
- DNAH5 | c.2329C>A p.H777N | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.209); catalogued as COSV54231183, COSV54237929; called by muse, mutect2, varscan2
- DNAH7 | c.6062C>T p.S2021L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV56773933; called by muse, mutect2, varscan2
- DNAI2 | c.1312A>C p.M438L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56760611; called by muse, varscan2
- DNAI3 | c.1600dup p.Q534Pfs*12 | Frame Shift Ins (INS) | VAF 7/39 reads (18%) | catalogued as rs781774059; called by mutect2, pindel, varscan2
- DNMT3B | c.2339C>G p.S780W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52416193, COSV52420343; called by muse, mutect2, varscan2
- DRD2 | c.92G>C p.R31T | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV60760092; called by muse, mutect2, varscan2
- DYNC2H1 | c.11514G>C p.K3838N | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.395); catalogued as COSV62093229, COSV62099494; called by muse, mutect2, varscan2
- EHBP1 | c.2923G>C p.E975Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV50425940, COSV50445805; called by muse, mutect2, varscan2
- EHBP1 | c.3250G>C p.E1084Q | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50426002; called by muse, mutect2, varscan2
- EIF2AK1 | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748753246, COSV52236624, COSV99551780; called by muse, mutect2
- ENPP3 | c.2446G>C p.E816Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62955208; called by muse, mutect2, varscan2
- EP300 | c.4017G>A p.M1339I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54337752; called by muse, mutect2, varscan2
- EP300 | c.4040G>C p.G1347A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54337760; called by muse, varscan2
- EP300 | c.4170G>C p.Q1390H | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54337770; called by muse, varscan2
- EP300 | c.4333G>A p.D1445N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54327113, COSV54337780; called by muse, mutect2, varscan2
- EP300 | c.4650G>T p.K1550N | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54337791; called by muse, varscan2
- EPOR | c.474G>C p.E158D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as rs775300179, COSV55800909; called by muse, mutect2, varscan2
- F13A1 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53562124; called by muse, mutect2, varscan2
- FAM120A | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 151/194 reads (78%) | catalogued as COSV99465085; called by muse, mutect2, varscan2
- FBXL14 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV59336990; called by muse, mutect2, varscan2
- FBXO9 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as COSV55056406; called by muse, mutect2, varscan2
- FCRL1 | c.150C>A p.F50L | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63824057, COSV63826243; called by muse, mutect2
- FLRT2 | c.335G>A p.R112K | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV58145669; called by muse, mutect2, varscan2
- FOXK2 | c.1013C>G p.S338C | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.589); catalogued as COSV100081968, COSV58878733; called by muse, mutect2, varscan2
- FOXL2NB | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as COSV57728427; called by muse, mutect2, varscan2
- FRAS1 | c.8944C>G p.L2982V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); catalogued as COSV53598210, COSV53625995; called by muse, mutect2, varscan2
- FREM1 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV66526436; called by muse, varscan2
- FSTL4 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54777266; called by muse, mutect2, varscan2
- GNAI3 | c.361C>G p.P121A | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs901759563, COSV63984116; called by muse, mutect2, varscan2
- GPR31 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.338); catalogued as rs756916147, COSV64761079; called by mutect2, varscan2
- GPR37L1 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.773); catalogued as COSV100938534; called by mutect2, varscan2
- GPR50 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.06); catalogued as COSV54440717; called by muse, mutect2, varscan2
- H1-5 | c.131C>G p.S44* | Nonsense Mutation (SNP) | VAF 46/105 reads (44%) | catalogued as COSV100137825, COSV100138069; called by muse, mutect2, varscan2
- HADHB | c.553G>C p.D185H | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV58546609; called by muse, mutect2, varscan2
- HDGFL1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs1160289280, COSV57752419; called by muse, mutect2, varscan2
- HECW2 | c.2479G>C p.D827H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53665794, COSV53668820; called by muse, mutect2, varscan2
- HEPHL1 | c.924C>G p.F308L | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.866); catalogued as COSV59893867; called by muse, mutect2, varscan2
- HEYL | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65721818, COSV65721859; called by muse, varscan2
- HFM1 | c.3359C>G p.S1120* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV54031945, COSV99645833; called by muse, mutect2, varscan2
- HLA-DMB | c.453G>C p.K151N | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV66870862; called by muse, mutect2, varscan2
- HMCN1 | c.5402G>A p.G1801D | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777863596, COSV54917030; called by muse, mutect2, varscan2
- HMCN1 | c.11449G>C p.V3817L | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV54917040; called by muse, mutect2, varscan2
- HMCN1 | c.13997G>C p.R4666T | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54917053; called by muse, mutect2
- HMCN1 | c.13998A>T p.R4666S | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV54917068; called by muse, mutect2
- HMOX1 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs143057716; called by muse, mutect2, varscan2
- IDH3A | c.74G>C p.R25T | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV55113779; called by muse, mutect2, varscan2
- IFT140 | c.2492G>A p.R831H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs769046641, COSV54153684; called by muse, varscan2
- IFT80 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV58449778; called by muse, mutect2, varscan2
- IL17RC | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.511); catalogued as rs112532783; called by muse, mutect2, varscan2
- IL1F10 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464268639, COSV61750769; called by muse, mutect2
- IL1RAPL1 | c.1188A>T p.E396D | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100146942, COSV56278192; called by muse, mutect2, varscan2
- IMPG1 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100885731, COSV64059618; called by muse, mutect2, varscan2
- INCENP | c.1813C>G p.Q605E (on ENST00000394818 / NM_001040694.2; = p.Q601E on NM_020238.3) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.581); catalogued as COSV53915628, COSV53917927, COSV99610877; called by muse, mutect2, varscan2
- IRX5 | c.1322G>C p.G441A | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58059296, COSV58059422; called by muse, mutect2, varscan2
- ITGAL | c.1916C>T p.S639L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.696); catalogued as COSV63323231; called by muse, mutect2, varscan2
- ITGB4 | c.3162G>A p.W1054* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as COSV99563837; called by muse, varscan2
- JMJD1C | c.4262C>G p.S1421* | Nonsense Mutation (SNP) | VAF 42/120 reads (35%) | catalogued as COSV100550033; called by muse, mutect2, varscan2
- KAT6A | c.2173C>G p.Q725E | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV55908493; called by muse, mutect2
- KCNIP4 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.243); catalogued as COSV62853124; called by muse, mutect2, varscan2
- KIDINS220 | c.3772G>C p.E1258Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56755804, COSV99875464; called by muse, mutect2, varscan2
- KIF15 | c.1780G>C p.E594Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); catalogued as COSV58162671; called by muse, mutect2, varscan2
- KLHL11 | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV100044275, COSV59861724; called by muse, mutect2, varscan2
- KNOP1 | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); catalogued as COSV54928960; called by mutect2, varscan2
- KRT33B | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52441235; called by muse, mutect2, varscan2
- LAMC3 | c.2343G>C p.Q781H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV63093442; called by muse, mutect2, varscan2
- LCT | c.3709G>A p.D1237N | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV51553135; called by muse, mutect2, varscan2
- LRRC15 | c.1585G>A p.V529I | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs748636707, COSV61650742; called by mutect2, varscan2
- LRRC39 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.696); catalogued as COSV61583390; called by muse, mutect2, varscan2
- MACF1 | c.20863G>C p.E6955Q (on ENST00000372915; = p.E5000Q on NM_012090.5) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV57131314; called by muse, mutect2, varscan2
- MAN1C1 | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56046610; called by muse, mutect2, varscan2
- MAP2K4 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV62258809; called by muse, mutect2, varscan2
- MAP3K15 | c.3215C>T p.S1072L | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.996); catalogued as COSV58830458, COSV58833295; called by muse, mutect2, varscan2
- MAPK15 | c.915G>C p.Q305H | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV62027308, COSV62029110; called by muse, varscan2
- MAPRE3 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs771311276, COSV51867080; called by muse, mutect2, varscan2
- MCCD1 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV66019755; called by muse, mutect2, varscan2
- MCF2L2 | c.848A>C p.N283T | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV61057226, COSV61057754; called by muse, mutect2
- METAP2 | c.1273G>C p.E425Q | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.131); catalogued as COSV51565390; called by muse, varscan2
- METTL2B | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as COSV52309654; called by muse, mutect2, varscan2
- MKI67 | c.1219G>C p.D407H | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV64075466; called by muse, mutect2, varscan2
- MKRN2 | c.860C>G p.S287C | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99403134; called by muse, mutect2
- MPND | c.1203G>C p.K401N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.468); catalogued as COSV53658388; called by muse, varscan2
- MROH2B | c.4513C>T p.L1505F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.547); catalogued as COSV68186577; called by muse, mutect2, varscan2
- MTHFD2L | c.271G>C p.D91H (on ENST00000395759 / NM_001144978.2; = p.D33H on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); catalogued as COSV57468721; called by muse, mutect2, varscan2
- MYCBP2 | c.13622C>G p.S4541C (on ENST00000357337; = p.S4579C on NM_015057.5) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62028344; called by muse, mutect2, varscan2
- MYL12B | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52898871; called by muse, mutect2, varscan2
- NBN | c.484A>G p.I162V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750594114, COSV55374651; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NBR1 | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV57833843; called by muse, mutect2, varscan2
- NELFB | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100546855; called by mutect2, varscan2
- NFKBIB | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs769713396, COSV58004097; called by muse, mutect2, varscan2
- NHLRC2 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0.022); catalogued as COSV65175376; called by muse, mutect2, varscan2
- NOB1 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs772834575, COSV52062367; called by muse, varscan2
- NOTCH3 | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as COSV54640362; called by muse, mutect2, varscan2
- NR1D2 | c.1623G>A p.M541I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV56992734; called by mutect2, varscan2
- NSFL1C | c.581A>G p.D194G | Missense Mutation (SNP) | VAF 22/187 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs751621318, COSV53794305; called by muse, mutect2, varscan2
- OPA1 | c.2934G>C p.K978N (on ENST00000361510 / NM_130837.3; = p.K923N on NM_015560.3) | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100655265; called by muse, mutect2
- OR13G1 | c.169T>A p.Y57N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62944724; called by muse, mutect2, varscan2
- OR9I1 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.066); catalogued as COSV56926962; called by muse, mutect2, varscan2
- PCDH9 | c.2393G>A p.R798K | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.95); PolyPhen benign (0.439); catalogued as COSV60568054; called by muse, mutect2, varscan2
- PFKFB3 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 10/70 reads (14%) | PolyPhen benign (0.07); catalogued as COSV57990656; called by muse, mutect2, varscan2
- PIH1D1 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51807845; called by muse, mutect2, varscan2
- PKIB | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1191535946, COSV57796219; called by muse, mutect2, varscan2
- PLA2G15 | c.785C>G p.S262* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as COSV99547168; called by muse, mutect2, varscan2
- PLXDC2 | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65906090; called by mutect2, varscan2
- POLQ | c.5801C>G p.S1934C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV51756515; called by muse, mutect2, varscan2
- PPL | c.3434G>A p.R1145H | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs74787749; called by muse, mutect2, varscan2
- PRDM2 | c.4960C>T p.Q1654* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV99341348; called by muse, mutect2, varscan2
- PROS1 | c.1238T>C p.L413P | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67776121; called by muse, mutect2, varscan2
- PRUNE2 | c.8596T>C p.S2866P | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV56317800; called by muse, mutect2, varscan2
- PRUNE2 | c.6113C>G p.S2038C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs754573220, COSV65037549; called by muse, mutect2, varscan2
- PTCD1 | c.1401G>C p.L467F | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52865238, COSV99463806; called by muse, mutect2, varscan2
- PTPN22 | c.1052C>G p.S351C (on ENST00000359785 / NM_001193431.2; = p.S296C on NM_012411.5) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV63085762; called by muse, mutect2, varscan2
- PTPRK | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV63887719; called by muse, mutect2, varscan2
- PTPRM | c.758G>C p.R253P | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV59847254, COSV59869553; called by muse, mutect2, varscan2
- PUM1 | c.2817G>C p.Q939H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV57088252; called by muse, mutect2, varscan2
- PYGM | c.549G>A p.W183* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as rs1223885403, COSV99376969; called by muse, mutect2, varscan2
- RBM39 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV53613778, COSV99488424; called by muse, mutect2
- RGS19 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58658478; called by muse, mutect2, varscan2
- RPL10A | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV57690434; called by muse, mutect2, varscan2
- SACS | c.3787C>G p.L1263V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV66543487; called by muse, mutect2, varscan2
- SEC24A | c.2860G>A p.D954N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.561); catalogued as COSV67305797; called by muse, mutect2, varscan2
- SETMAR | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.147); catalogued as rs1406499426, COSV62781120; called by muse, mutect2, varscan2
- SHANK2 | c.4690C>T p.Q1564* | Nonsense Mutation (SNP) | VAF 38/145 reads (26%) | catalogued as COSV99573265; called by muse, varscan2
- SIGLEC1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.318); catalogued as COSV52459061, COSV52467556; called by muse, mutect2, varscan2
- SLC10A3 | c.31C>G p.Q11E | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); catalogued as COSV54836765; called by muse, mutect2, varscan2
- SLC32A1 | c.348C>G p.I116M | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV54147468; called by muse, mutect2, varscan2
- SLC47A1 | c.1662C>G p.F554L | Missense Mutation (SNP) | VAF 81/169 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV54502475; called by muse, mutect2, varscan2
- SLC4A1AP | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58136086; called by muse, varscan2
- SLC5A10 | c.1148C>G p.S383C (on ENST00000395645 / NM_001042450.4; = p.S399C on NM_152351.5) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100525262, COSV58759945; called by muse, mutect2, varscan2
- SLC7A3 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV53229756, COSV99979486; called by muse, mutect2, varscan2
- SMCHD1 | c.5006G>A p.R1669Q | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs368367743, COSV55251756; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMG8 | c.2760G>T p.Q920H | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.725); catalogued as COSV56286172; called by muse, mutect2
- SORBS1 | c.3325G>A p.D1109N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV53360805; called by muse, mutect2, varscan2
- SPAG9 | c.2644G>A p.D882N (on ENST00000262013 / NM_001130528.3; = p.D868N on NM_003971.6) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV56238806; called by muse, varscan2
- SPAG9 | c.2638G>A p.E880K (on ENST00000262013 / NM_001130528.3; = p.E866K on NM_003971.6) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56238823; called by muse, varscan2
- SPARCL1 | c.663G>C p.K221N | Missense Mutation (SNP) | VAF 63/376 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV56805032; called by muse, mutect2, varscan2
- SPATA21 | c.726G>C p.Q242H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as rs1354707891, COSV59187756, COSV59188834; called by muse, varscan2
- SPIRE2 | c.1861G>C p.E621Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as COSV54530344; called by muse, mutect2, varscan2
- SPOCD1 | c.3135G>C p.K1045N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV57097856; called by muse, varscan2
- SPRED1 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54437401, COSV54439454; called by muse, mutect2, varscan2
- SPTB | c.3465G>C p.R1155S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV67633372; called by muse, mutect2, varscan2
- STK26 | c.127G>C p.D43H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.684); catalogued as COSV61230351; called by muse, mutect2, varscan2
- STK4 | c.1186C>G p.L396V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV65670908; called by muse, mutect2, varscan2
- SYCP2L | c.2418C>G p.F806L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV51655194; called by muse, mutect2, varscan2
- TBL1XR1 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV61791541; called by muse, mutect2, varscan2
- TMPRSS11F | c.777G>C p.W259C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62467707; called by muse, varscan2
- TMPRSS15 | c.1029G>C p.E343D | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as rs1261587905, COSV53043285; called by muse, mutect2, varscan2
- TP73 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs747896985, COSV60703876; called by muse, varscan2
- TRABD | c.624G>C p.Q208H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57713587; called by muse, mutect2, varscan2
- TREX1 | c.525G>C p.K175N (on ENST00000625293 / NM_033629.6; = p.K165N on NM_007248.5) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV56497441, COSV99604105; called by muse, mutect2
- TREX1 | c.839G>T p.G280V (on ENST00000625293 / NM_033629.6; = p.G270V on NM_007248.5) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.071); catalogued as CD1313198, COSV56497451; called by muse, mutect2, varscan2
- TRIM62 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.025); catalogued as rs1191921675, COSV52221910; called by muse, mutect2, varscan2
- TRPS1 | c.1925C>T p.S642L (on ENST00000220888 / NM_001330599.2; = p.S655L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs367794981; called by muse, mutect2, varscan2
- TTK | c.653C>G p.S218* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as COSV100036172; called by muse, mutect2, varscan2
- TTLL7 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV53086302; called by muse, mutect2, varscan2
- TXNRD1 | c.1532C>T p.S511F (on ENST00000525566 / NM_001093771.3; = p.S413F on NM_003330.4) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV100723397; called by muse, mutect2, varscan2
- UBR5 | c.6713G>C p.R2238T | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV55293006; called by muse, mutect2
- UNC5C | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as rs931922530, COSV71661081; called by muse, mutect2, varscan2
- USP21 | c.790G>C p.D264H | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57091507; called by muse, mutect2
- UTP20 | c.3994G>C p.E1332Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV55380809; called by muse, mutect2, varscan2
- UTRN | c.2815G>A p.D939N | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV62340748; called by muse, mutect2, varscan2
- WDR72 | c.2414G>A p.W805* | Nonsense Mutation (SNP) | VAF 30/204 reads (15%) | catalogued as COSV100854350; called by muse, mutect2, varscan2
- ZEB1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV58046673; called by muse, mutect2
- ZFC3H1 | c.362C>G p.S121W | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs886420918, COSV57348213, COSV57349287; called by muse, varscan2
- ZFC3H1 | c.238C>G p.Q80E | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.025); catalogued as COSV57349300; called by muse, varscan2
- ZFHX3 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99196670; called by mutect2, varscan2
- ZMYM2 | c.1486C>G p.Q496E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.27); catalogued as COSV67034380, COSV67035832; called by muse, mutect2
- ZNF136 | c.983G>C p.R328T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV59711227; called by muse, mutect2, varscan2
- ZNF223 | c.902C>G p.S301* | Nonsense Mutation (SNP) | VAF 13/99 reads (13%) | catalogued as COSV71571811, COSV71571927; called by muse, mutect2, varscan2
- ZNF343 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as rs770545655, COSV53853512, COSV53854117; called by muse, mutect2, varscan2
- ZNF43 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.877); catalogued as COSV61684747; called by muse, mutect2, varscan2
- ZNF486 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as COSV58720617; called by muse, mutect2, varscan2
- ZNF662 | c.953C>A p.A318D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.209); catalogued as COSV100066222; called by muse, mutect2, varscan2
- ZNF662 | c.1202C>A p.S401Y | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.118); catalogued as COSV100066233; called by muse, varscan2
- IGKV3D-20 | c.72G>C p.L24F | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- METTL2A | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- PXT1 | c.344del p.F115Sfs*84 | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | called by mutect2, pindel, varscan2
- ZNF225 | c.435_436del p.K146Tfs*3 | Frame Shift Del (DEL) | VAF 15/113 reads (13%) | called by mutect2, pindel, varscan2
- ABCA3 | c.5064C>G p.V1688= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV57056303; called by muse, mutect2, varscan2
- AHNAK2 | c.3825G>C p.L1275= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV100317523, COSV60921541; called by muse, mutect2, varscan2
- ANGPTL7 | c.333C>T p.I111= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV63874490; called by muse, mutect2, varscan2
- APOL6 | c.189C>T p.L63= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs377013101; called by muse, varscan2
- ASPRV1 | c.804G>C p.L268= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV57228575; called by muse, mutect2, varscan2
- BICDL2 | c.30G>A p.P10= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs372212421, COSV66369943; called by muse, mutect2, varscan2
- BICRAL | c.1887G>A p.K629= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV58407035; called by muse, mutect2, varscan2
- CACHD1 | c.1672C>T p.L558= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as COSV51556579; called by muse, mutect2, varscan2
- CADM3 | c.855C>T p.I285= (on ENST00000368125 / NM_001127173.3; = p.I319= on NM_021189.5) | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as COSV63686304; called by muse, mutect2, varscan2
- CARD16 | c.513C>T p.L171= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as COSV65213163; called by muse, mutect2
- CASKIN1 | c.504C>G p.L168= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV58871316, COSV58874410; called by muse, mutect2, varscan2
- CD276 | c.72C>T p.C24= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100573335; called by muse, mutect2
- CD37 | c.84G>C p.L28= | Silent (SNP) | VAF 56/430 reads (13%) | catalogued as rs962809466, COSV60544840; called by muse, varscan2
- CDK10 | c.492G>A p.L164= (on ENST00000353379 / NM_052988.5; = p.L93= on NM_052987.4) | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV57047733; called by muse, mutect2, varscan2
- CERS4 | c.603C>G p.V201= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV52168454; called by muse, mutect2, varscan2
- CNIH2 | c.147G>T p.R49= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV61012756; called by mutect2, varscan2
- CXCL1 | c.234C>G p.L78= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs780191003, COSV67611745; called by muse, mutect2, varscan2
- DEFB119 | c.192C>T p.S64= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as rs1442344452, COSV53620853; called by muse, mutect2, varscan2
- DENND4B | c.483C>T p.I161= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV57844049; called by muse, mutect2, varscan2
- ECT2L | c.2451C>T p.L817= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV57812229; called by muse, mutect2, varscan2
- EGF | c.885G>A p.L295= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV54480684; called by muse, mutect2, varscan2
- EP300 | c.4689G>C p.L1563= | Silent (SNP) | VAF 40/140 reads (29%) | catalogued as COSV54337801, COSV99609725; called by muse, varscan2
- EPB41L1 | c.525C>T p.F175= | Silent (SNP) | VAF 21/80 reads (26%) | catalogued as rs774456412, COSV52440488, COSV99148757; called by muse, mutect2, varscan2
- ERCC2 | c.1221C>T p.V407= | Silent (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- FAM155B | c.672G>A p.L224= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV52935839; called by muse, mutect2
- FBXL13 | c.1947C>A p.I649= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV57540747; called by muse, mutect2, varscan2
- FICD | c.399C>G p.L133= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV57208703; called by muse, mutect2, varscan2
- FLT4 | c.123C>T p.I41= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs762374955, COSV56099561; called by muse, mutect2, varscan2
- FOXRED1 | c.246G>A p.L82= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV55007698; called by muse, mutect2, varscan2
- GLTP | c.546C>G p.L182= | Silent (SNP) | VAF 128/341 reads (38%) | catalogued as COSV59172801; called by muse, mutect2, varscan2
- HACD1 | c.357G>A p.Q119= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV63516717; called by muse, mutect2, varscan2
- IFT140 | c.2439G>A p.K813= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1289609387, COSV99559852; called by muse, varscan2
- IMPG2 | c.975C>T p.L325= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV51978088; called by muse, mutect2, varscan2
- INSR | c.2157C>T p.I719= | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as rs1270708644, COSV57166753; called by muse, mutect2, varscan2
- KHDC3L | c.435G>A p.T145= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV64863674; called by muse, mutect2, varscan2
- KIF2C | c.204C>G p.L68= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV64765057; called by muse, mutect2, varscan2
- MRC1 | c.1953C>T p.G651= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs945635224; called by muse, mutect2, varscan2
- MUC17 | c.2580T>C p.Y860= | Silent (SNP) | VAF 97/376 reads (26%) | catalogued as rs764384509, COSV60295129; called by muse, mutect2, varscan2
- NAV2 | c.6207C>T p.V2069= (on ENST00000396087 / NM_001244963.2; = p.V2010= on NM_145117.5) | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as rs752631285, COSV100217590, COSV60661681; called by muse, mutect2, varscan2
- NCK2 | c.672G>C p.V224= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV51893254; called by muse, mutect2, varscan2
- NFIC | c.150G>T p.S50= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as COSV59414151, COSV59418099; called by muse, mutect2, varscan2
- NLRP5 | c.2841C>T p.L947= | Silent (SNP) | VAF 47/80 reads (59%) | catalogued as rs369071652; called by muse, mutect2, varscan2
- NLRP8 | c.852C>T p.L284= | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as COSV52584032, COSV52590417; called by muse, mutect2, varscan2
- NOSIP | c.633C>T p.R211= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV59199418; called by muse, mutect2, varscan2
- NTM | c.225C>G p.L75= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as COSV66185455; called by muse, mutect2, varscan2
- NUP54 | c.1137C>G p.L379= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV53576393; called by muse, mutect2, varscan2
- OR11H12 | c.912C>T p.I304= | Silent (SNP) | VAF 35/134 reads (26%) | catalogued as COSV101612479; called by muse, mutect2, varscan2
- OR14K1 | c.243C>G p.L81= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV51721836, COSV51722207; called by muse, mutect2, varscan2
- OR5AP2 | c.633T>C p.F211= | Silent (SNP) | VAF 8/177 reads (5%) | catalogued as COSV57258048; called by muse, mutect2
- PDHA2 | c.552C>T p.N184= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs1448922583, COSV54779922; called by muse, mutect2
- PHIP | c.1851C>T p.L617= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV51502707, COSV51507068; called by muse, mutect2, varscan2
- PTH2R | c.792C>G p.L264= | Silent (SNP) | VAF 22/172 reads (13%) | catalogued as COSV55917827; called by muse, mutect2, varscan2
- PTPRJ | c.1155C>A p.I385= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV69253225; called by muse, mutect2, varscan2
- RAF1 | c.1653C>T p.I551= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV50106161; called by muse, mutect2, varscan2
- RASA3 | c.1524G>A p.T508= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs202142638, COSV61869931; called by muse, mutect2, varscan2
- REL | c.114G>A p.E38= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV54365570; called by muse, mutect2, varscan2
- RNF14 | c.741G>A p.L247= | Silent (SNP) | VAF 18/149 reads (12%) | catalogued as COSV61662603; called by muse, mutect2, varscan2
- SCN4A | c.4206C>G p.L1402= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV71127752; called by muse, mutect2, varscan2
- SEMG1 | c.987G>A p.Q329= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs768778177, COSV54871793; called by muse, mutect2, varscan2
- SHANK2 | c.3729C>G p.L1243= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as COSV53594862, COSV53607585; called by muse, mutect2, varscan2
- SHPRH | c.5051G>A p.*1684= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99261846; called by muse, mutect2, varscan2
- SLC9A4 | c.312C>T p.I104= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV54836380; called by muse, mutect2, varscan2
- SPOCD1 | c.3177G>A p.L1059= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs1405222191, COSV57097842; called by muse, varscan2
- SUPT20HL2 | c.1746C>T p.V582= | Silent (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- TBC1D5 | c.642C>G p.V214= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV53763185, COSV99508858; called by muse, mutect2, varscan2
- TM9SF4 | c.1917G>A p.V639= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV54108981; called by muse, mutect2, varscan2
- TMEM131 | c.4014G>A p.A1338= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs762695162, COSV51771269; called by muse, mutect2, varscan2
- TREX1 | c.261G>C p.L87= (on ENST00000625293 / NM_033629.6; = p.L77= on NM_007248.5) | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as COSV56496254; called by muse, mutect2, varscan2
- TTN | c.9924C>G p.V3308= (on ENST00000591111; = p.V3262= on NM_003319.4) | Silent (SNP) | VAF 29/108 reads (27%) | catalogued as COSV60011163, COSV60180903; called by muse, mutect2, varscan2
- TUBG2 | c.804C>T p.F268= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as rs1246283414, COSV52218649; called by muse, mutect2, varscan2
- TUBGCP5 | c.2952A>G p.E984= | Silent (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- TUBGCP5 | c.2679C>T p.F893= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as rs1435605399; called by muse, mutect2, varscan2
- UGT3A2 | c.1116G>A p.Q372= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV56931868; called by muse, mutect2, varscan2
- VARS1 | c.1731C>T p.F577= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs746698385, COSV63304888; called by muse, mutect2
- WDR55 | c.252C>T p.L84= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV64225967; called by muse, mutect2, varscan2
- WDR55 | c.615C>G p.L205= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs1332413158, COSV56908026; called by muse, mutect2, varscan2
- XPNPEP2 | c.1095C>G p.L365= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV64368402; called by muse, mutect2, varscan2
- ZNF883 | c.654C>T p.F218= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV71309167; called by muse, varscan2
- ZPLD1 | c.900C>G p.L300= (on ENST00000466937 / NM_001329788.1; = p.L316= on NM_175056.2) | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV60354765; called by muse, mutect2, varscan2
- CNOT11 | chr2:101273046 C>G | 3'Flank (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- NPR3 | c.*3324C>A | 3'UTR (SNP) | VAF 19/78 reads (24%) | catalogued as COSV54090032, COSV99423710; called by muse, mutect2, varscan2
- OTOR | c.-1G>A | 5'UTR (SNP) | VAF 20/118 reads (17%) | catalogued as COSV99856154, COSV99856228; called by muse, mutect2, varscan2
- RPL4 | c.422-140G>T | Intron (SNP) | VAF 10/62 reads (16%) | catalogued as rs1018291649, COSV100328560; called by muse, mutect2, varscan2
